MMRF case MMRF_1994 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/1eb5a034-f107-42f8-ac42-b0fe57514701

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 89 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 89.8 years (32,805 days); ISS stage: III; Days to last known disease status: 272 days; Days to last follow up: -3 days.

Follow-up (1 entry)
- Days to follow up: -3 days; ECOG performance status: 1.

Molecular and laboratory tests (values rounded to 3 significant figures where GDC's unit conversion carried more)
- Creatinine 61.9 µmol/L.
- Absolute Neutrophil 3.3 ×10⁹/L.
- Blood Urea Nitrogen 4.64 mmol/L.
- Glucose 5.83 mmol/L.
- Albumin 29 g/L.
- Serum Free Immunoglobulin Light Chain, Lambda 137 mg/dL.
- Immunoglobulin A 1.08 g/L.
- Immunoglobulin M 0.21 g/L.
- Platelets 59 ×10⁹/L.
- Calcium 2.38 mmol/L.
- Serum Free Immunoglobulin Light Chain, Kappa 0.43 mg/dL.
- Total Protein 5.8 g/dL.
- C-Reactive Protein 1.46 mg/dL.
- Lactate Dehydrogenase 7.92 µkat/L.
- Immunoglobulin G 3.48 g/L.
- Beta 2 Microglobulin 6.2 µg/mL.
- Hemoglobin 5.64 mmol/L.
- Leukocytes 4 ×10⁹/L.

Other clinical attributes
- Day -3: Weight: 54 kg; Height: 149 cm.

Family history
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Colorectal Cancer; Relationship sex at birth: male.
- Relative with cancer history: yes; Relationship type: Sibling.

Biospecimens (2 samples)
- Sample MMRF_1994_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -3 days.
- Sample MMRF_1994_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -3 days.
